Gene-level copy-number profile of tumor specimen TCGA-EB-A24C-01A from TCGA case TCGA-EB-A24C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.2 years (20,539 days).
Specimen TCGA-EB-A24C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6916f7ca-ea97-4041-8733-e274451c8e8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A24C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa2f9cd3-8424-4ecf-b93d-6975b8c88e11

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 19,032; copy number 3: 5,135; copy number 4: 31,205; copy number 5: 3,560; copy number 6: 444; copy number 8: 90; copy number 9: 114; copy number 10: 148; copy number 11: 77; copy number 12: 5; copy number 13: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A24C-01A-11D-A191-01): tumor purity 0.91, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 349 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:21,006,730–22,373,321, 5 genes, copy number 9 (within-gene range 2–9): AC099753.1, VENTXP7, ZNF385D, ZNF385D-AS1, ZNF385D-AS2.
- chr3:26,614,261–27,484,420, 7 genes, copy number 11 (within-gene range 2–11): AC099754.1, LRRC3B, NEK10, MICOS10P3, RNU6-342P, AC099535.2, SLC4A7.
- chr3:33,144,104–34,873,854, 19 genes, copy number 9–12: AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1.
- chr3:37,452,115–37,823,507, 1 gene, copy number 9 (within-gene range 2–9): ITGA9.
- chr3:37,693,655–40,260,321, 62 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr3:48,157,146–48,188,417, 1 gene, copy number 9 (within-gene range 2–9): CDC25A.
- chr3:48,180,328–48,662,886, 31 genes, copy number 9 (within-gene range 2–9): RNU7-128P, NDUFB1P1, MIR4443, CAMP, ZNF589, MRPS18AP1, Y_RNA, NME6, FCF1P2, SPINK8, MIR2115, FBXW12, RN7SL321P, PLXNB1, CCDC51, TMA7, AC134772.1, ATRIP, TREX1, SHISA5, PFKFB4, MIR6823, UCN2, COL7A1, MIR711, UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793.
- chr3:57,060,664–58,666,834, 47 genes, copy number 10: SPATA12, AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, AC092418.2, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16, FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D.
- chr3:63,545,440–64,003,462, 8 genes, copy number 11 (within-gene range 2–11): RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1.
- chr3:67,654,669–75,785,583, 120 genes, copy number 10–11 (within-gene range 1–11) (broad region; genes not listed).
- chr3:75,964,980–75,965,069, 1 gene, copy number 11: Y_RNA.
- chr3:80,442,081–84,051,419, 22 genes, copy number 10–13: AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:84,691,681–84,692,591, 1 gene, copy number 10: AC117482.1.
- chr3:84,958,989–87,324,723, 18 genes, copy number 11 (within-gene range 2–11): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25.
- chr3:89,047,442–90,030,495, 6 genes, copy number 10: GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
